Gene-level copy-number profile of tumor specimen TCGA-F1-A448-01A from TCGA case TCGA-F1-A448, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.8 years (25,846 days).
Specimen TCGA-F1-A448-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.051a9aea-7fd1-4536-a72b-3719e3860a03.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F1-A448-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/818955fd-a90e-4cd1-a503-cf0c5c0327f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,383; copy number 2: 53,293; copy number 3: 4,107; copy number 4: 17; copy number 5: 11; copy number 6: 8; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F1-A448-01A-11D-A24C-01): tumor purity 0.3, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:81,418,723–81,419,302, 1 gene, copy number 6: CHMP4AP1.
- chr3:29,926,811–29,934,156, 1 gene, copy number 6: RBMS3-AS1.
- chr3:105,366,909–105,576,900, 1 gene, copy number 6 (within-gene range 2–6): ALCAM.
- chr4:19,098,199–19,098,740, 1 gene, copy number 5: AC006840.1.
- chr4:57,841,721–57,855,271, 1 gene, copy number 5: AC104790.1.
- chr4:70,334,981–70,337,116, 1 gene, copy number 6: CABS1.
- chr6:95,917,143–96,015,391, 2 genes, copy number 5 (within-gene range 2–5): AL034348.1, KRT18P50.
- chr6:114,822,994–115,002,280, 2 genes, copy number 5 (within-gene range 2–5): AL590550.1, RNU6-475P.
- chr6:115,633,540–115,643,916, 1 gene, copy number 5: LINC02534.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 6: AC139365.2, AC139365.1.
- chr8:64,331,927–64,332,152, 1 gene, copy number 6: COX6CP8.
- chr8:87,575,598–87,576,508, 1 gene, copy number 5: VTA1P2.
- chr8:119,325,171–119,325,265, 1 gene, copy number 5: MIR548AZ.
- chr11:50,409,042–50,422,316, 1 gene, copy number 8: AC024405.1.
- chr12:28,505,394–28,505,528, 1 gene, copy number 5: RNA5SP355.
- chr12:37,575,587–37,576,384, 1 gene, copy number 5: ZNF970P.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
